TCGA case TCGA-2G-AAKO — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/22a82b1a-c799-40d9-8ff4-09b093947263

Demographics
Sex at birth: male; Country of residence at enrollment: Netherlands.

Diagnoses (1)
1. Primary of the testis (histology not recorded by GDC). Site of resection or biopsy: Testis, NOS; Synchronous malignancy: No.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAKO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 210 mg.
  Slide TCGA-2G-AAKO-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-2G-AAKO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAKO-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Initial weight: 110 mg.
  Slide TCGA-2G-AAKO-05A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-2G-AAKO-05Z: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAKO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAKO-01A-11D-A42X-01): tumor purity 0.13, ploidy 4.78, whole-genome doublings 2.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAKO-05A-11D-A42X-01): tumor purity 0.41, ploidy 3.99, whole-genome doublings 1.
